Gene-level copy-number profile of tumor specimen TCGA-55-8096-01A from TCGA case TCGA-55-8096, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.6 years (24,684 days).
Specimen TCGA-55-8096-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.44b803e1-677e-4c07-bf45-4c185c3f97f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8096-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1671f094-e402-4673-a37b-0c99f3bf7b24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 4,553; copy number 2: 31,678; copy number 3: 15,917; copy number 4: 4,161; copy number 5: 1,827; copy number 6: 582; copy number 7: 844; copy number 8: 123; copy number 10: 89; copy number 16: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8096-01A-11D-2237-01): tumor purity 0.25, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,502 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:12,639,086–15,705,565, 39 genes, copy number 5: ECM1P2, AC093809.1, AC007370.2, AC007370.1, U6, HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63, CPEB2-DT, CPEB2, C1QTNF7-AS1, RN7SKP170, C1QTNF7, AC099550.1, CC2D2A, AC007016.1, AC116651.1, FBXL5, FAM200B, AC114744.2.
- chr4:31,171,013–31,558,831, 3 genes, copy number 5: LINC02497, AC104071.1, LINC02501.
- chr4:38,758,791–52,551,574, 193 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–56,321,397, 819 genes, copy number 6–7 (broad region; genes not listed).
- chr7:10,449,820–10,779,944, 1 gene, copy number 7 (within-gene range 4–7): MGC4859.
- chr7:10,702,676–32,894,131, 359 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:44,044,640–62,275,678, 308 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr7:102,813,230–103,074,843, 1 gene, copy number 5 (within-gene range 3–5): FBXL13.
- chr7:102,913,000–105,115,019, 32 genes, copy number 5 (within-gene range 1–5): LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E.
- chr8:126,556,323–127,419,050, 1 gene, copy number 6 (within-gene range 3–6): PCAT1.
- chr8:127,072,694–140,517,154, 142 genes, copy number 6 (broad region; genes not listed).
- chr8:143,157,914–145,066,685, 130 genes, copy number 5 (broad region; genes not listed).
- chr12:57,604,622–59,064,238, 45 genes, copy number 8–16 (within-gene range 3–16): DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr16:11,555–35,912,516, 1,419 genes, copy number 5 (broad region; genes not listed).
- chr21:14,676,698–15,065,936, 10 genes, copy number 5 (within-gene range 2–5): AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2.

Autosomal genes at a single copy (total copy number 1): 4,553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
